TCGA case TCGA-24-2293 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bdd792e7-d75f-4aa3-b38e-f0708e112075

Demographics
Sex at birth: female; Race: white; Age at index: 47 years; Vital status: Dead; Days to death: 506 days (1.4 years).

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C48.1; Tissue or organ of origin: Specified parts of peritoneum; Site of resection or biopsy: Specified parts of peritoneum; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 47.2 years (17,235 days); Year of diagnosis: 1995; Method of diagnosis: Surgical Resection; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: >20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Treatment intent type: Adjuvant; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Melphalan; Treatment intent type: Adjuvant; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Number of cycles: 6; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 506.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-24-2293-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.3; Intermediate dimension: 1.1; Shortest dimension: 0.3.
  Slide TCGA-24-2293-01A-01-BS1: Section location: Bottom; Percent tumor cells: 40; Percent tumor nuclei: 66; Percent normal cells: 58; Percent necrosis: 2; Percent stromal cells: 0.
  Slide TCGA-24-2293-01A-01-TS1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 74; Percent normal cells: 43; Percent necrosis: 2; Percent stromal cells: 0.
- Sample TCGA-24-2293-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Omentum; Histologic diagnosis: Serous Cystadenocarcinoma; History neoadjuvant treatment: No; Anatomic organ subdivision: Right; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol.
- Follow-up form: Treatment outcome first course: Partial Remission/Response.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy of Ovarian cancer.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 506 days; disease-specific survival: event status not recorded, 506 days; progression-free interval: no event (censored), 506 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-24-2293-01A-01D-0704-01): tumor purity 0.39, ploidy 2.81, whole-genome doublings 1.
